Somatic mutation profile of tumor specimen 0DGUTC from CCDI case PBBUAB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (81 days).
Specimen 0DGUTC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27b04d4d-e754-40db-8cde-234edff12208.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGUSC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba1df687-ba77-46ba-bf0f-530590f5e2a0

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, RNA 2, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC5B | c.3290G>A p.R1097H | Missense Mutation (SNP) | VAF 38/628 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs202160055, COSV71590038; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 43/828 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 47/1006 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as rs1167537044; called by muse, mutect2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 27/314 reads (9%) | called by muse, mutect2
- LINC02694 | n.552G>A | RNA (SNP) | VAF 27/300 reads (9%) | catalogued as rs768118261; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/200 reads (13%) | called by muse, varscan2
